Surgical pathology report (de-identified scan), TCGA case TCGA-CV-7253, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-CV-7253-01A (Primary Tumor).

[page 1 of 2]
**** Case imported from legacy computer system. The format of this report does not match the original case. ****
**** For cases prior to [REDACTED], the section "SPECIMEN" may have been added. ****

SUPPLEMENTAL REPORT

DIAGNOSIS:

- (D) PORTION MANDIBLE, TONGUE, SOFT PALATE, HARD PALATE:
MODERATELY DIFFERENTIATED SQUAMOUS CARCINOMA FOCALLY INVADING
MANDIBLE; MANDIBULAR RESECTION MARGINS FREE OF TUMOR. (SEE
COMMENT)

COMMENT: This supplemental report is issued to give diagnosis on specimens
requiring decalcification. This report does not change any diagnosis given
on the previous report.

DIAGNOSIS

- (A) CARCINOMA LEFT BASE OF TONGUE:
Fragments of necrotic tissue containing single segment
of detached distorted dysplastic squamous tissue.
- (B) SUBDIGASTRIC AND MAXILLARY NODES:
Four lymph nodes, no tumor present.
Submandibular gland with focal atrophic changes and
fibrosis, no tumor present.
- (C) TISSUE FROM LEFT PTERYGOID FOSSA:
INVASIVE MODERATELY DIFFERENTIATED SQUAMOUS CARCINOMA.
MICROSCOPIC FOCI OF CARCINOMA PRESENT AT RESECTION
MARGIN.
Focal mucosal erosion.
- (D) PORTION MANDIBLE, TONGUE, SOFT PALATE, HARD PALATE:
INVASIVE MODERATELY DIFFERENTIATED SQUAMOUS CARCINOMA
INVOLVING TONGUE, TISSUE AT BASE OF TONGUE AND SOFT
TISSUE ADJACENT TO ANGLE OF MANDIBLE.
MICROSCOPIC FOCI OF TUMOR PRESENT IN POSTERIOR AND
ANTERIOR SOFT TISSUE RESECTION MARGINS (DEEP TO MUCOSA)
AND SOFT TISSUE MARGIN OF TISSUE ATTACHED TO MANDIBLE
(AT ANGLE).
Mucosal ulceration.
Mandible and mandibular resection margins, diagnosis pending
decalcification.

COMMENT

Focal vascular invasion by tumor is identified. There is no

[page 2 of 2]
[REDACTED]

unequivocal lymphatic or perineural invasion noted.

[REDACTED]

SPECIMEN

- (A) CARCINOMA LEFT BASE OF TONGUE:
- (B) SUBDIGASTRIC AND MAXILLARY NODES:
- (C) TISSUE FROM LEFT PTERYGOID FOSSA:
- (D) PORTION MANDIBLE, TONGUE, SOFT PALATE, HARD PALATE:

SNOMED CODES

T-53000,M-80703

Source: NCI Genomic Data Commons file 69f3e039-eeff-4bdd-94f0-7283196a4538 (TCGA-CV-7253.B459286E-999E-4B62-AB8A-C86248825FD1.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).